Gene-level copy-number profile of tumor specimen TCGA-4Z-AA7M-01A from TCGA case TCGA-4Z-AA7M, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 65.2 years (23,817 days).
Specimen TCGA-4Z-AA7M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.7d3268bb-4c9c-464d-8c1c-67e7d611d27c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA7M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcdd1b6a-33e7-4c3c-be81-f7ebb62a496e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,112; copy number 2: 17,595; copy number 3: 19,732; copy number 4: 11,784; copy number 5: 3,922; copy number 6: 3,556; copy number 7: 636; copy number 8: 215; copy number 9: 836; copy number 10: 71; copy number 12: 12; copy number 13: 18; copy number 14: 136; copy number 16: 20; copy number 17: 84; copy number 18: 8; copy number 19: 10; copy number 20: 30; copy number 22: 11; copy number 23: 10; copy number 24: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA7M-01A-11D-A390-01): tumor purity 0.6, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,101 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,641,816–198,540,945, 188 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr1:229,688,999–238,779,200, 185 genes, copy number 7–9 (broad region; genes not listed).
- chr1:239,052,748–244,451,909, 92 genes, copy number 9 (broad region; genes not listed).
- chr5:10,137,138–10,777,062, 36 genes, copy number 9: AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1.
- chr6:8,158,162–8,760,447, 1 gene, copy number 7 (within-gene range 6–7): AL355499.2.
- chr6:8,411,435–10,930,423, 34 genes, copy number 7 (within-gene range 5–7): SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK.
- chr7:70,972–16,888,885, 284 genes, copy number 7–9 (broad region; genes not listed).
- chr7:16,938,225–16,938,557, 1 gene, copy number 8: AC098592.1.
- chr7:17,299,295–17,467,256, 3 genes, copy number 10 (within-gene range 6–10): AC019117.3, SNORA63, AC019117.2.
- chr8:61,759,094–85,617,512, 354 genes, copy number 8–14 (broad region; genes not listed).
- chr8:87,540,835–102,124,907, 258 genes, copy number 9–17 (within-gene range 2–17) (broad region; genes not listed).
- chr10:4,747,846–7,118,469, 67 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr11:34,051,731–34,663,288, 12 genes, copy number 7 (within-gene range 2–7): CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF.
- chr12:87,746,567–88,602,195, 19 genes, copy number 8: AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3, RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr13:73,054,976–73,113,018, 3 genes, copy number 9: KLF5, FABP5P1, RNU6-66P.
- chr16:23,167,577–24,572,863, 38 genes, copy number 7–12: AC099482.2, SCNN1G, AC099482.1, SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2, NDUFAB1, PALB2, AC008870.4, DCTN5, AC008870.1, PLK1, AC008870.3, ERN2, AC008870.5, AC012317.1, AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6.
- chr16:24,661,422–24,671,062, 1 gene, copy number 12: LINC01567.
- chr17:32,444,379–35,578,863, 104 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:35,596,904–35,597,128, 1 gene, copy number 9: AC004134.1.
- chr17:45,506,741–48,430,275, 107 genes, copy number 7 (broad region; genes not listed).
- chr17:52,390,515–53,106,358, 4 genes, copy number 8: LINC01982, LINC02089, LINC02876, MTCO1P40.
- chr17:54,968,727–55,872,939, 12 genes, copy number 8 (within-gene range 4–8): STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr17:58,982,638–64,308,690, 184 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr19:27,793,431–27,984,984, 1 gene, copy number 19 (within-gene range 6–19): AC006504.5.
- chr19:27,805,423–30,085,893, 55 genes, copy number 10–24: SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:30,907,199–32,869,767, 38 genes, copy number 18–20: LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3, PDCD5, ANKRD27, SNORA68B, RPS12P31, RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22.
- chr19:33,386,950–33,521,791, 1 gene, copy number 19 (within-gene range 4–19): PEPD.
- chr19:49,906,825–50,310,542, 18 genes, copy number 13 (within-gene range 4–13): NUP62, AC011452.1, ATF5, MIR4751, SIGLEC11, U3, SIGLEC16, VRK3, Metazoa_SRP, ZNF473, AC010624.3, AC010624.1, AC010624.4, AC010624.2, AC010624.5, IZUMO2, MYH14, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
